Gene-level copy-number profile of tumor specimen TCGA-VQ-A91Q-01A from TCGA case TCGA-VQ-A91Q, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 61.1 years (22,303 days).
Specimen TCGA-VQ-A91Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.82e36346-b30a-4474-a340-d6e1894755e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A91Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/db965fb0-2bd6-4b93-ba1e-65e8741d7df0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 19,256; copy number 2: 35,735; copy number 3: 3,375; copy number 4: 831; copy number 5: 356; copy number 6: 69; copy number 8: 38; copy number 11: 15; copy number 15: 42; copy number 18: 32; copy number 19: 58; copy number 20: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A91Q-01A-12D-A40Z-01): tumor purity 0.71, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:96,518,110–96,587,452, 2 genes: TM9SF3, NPM1P26.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 613 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:188,151,206–193,697,811, 57 genes, copy number 5: LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2, AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA.
- chr3:197,293,878–198,222,513, 35 genes, copy number 6: MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr7:102,748,971–102,809,225, 1 gene, copy number 6 (within-gene range 3–6): FAM185A.
- chr7:102,813,230–104,907,232, 28 genes, copy number 6 (within-gene range 1–6): FBXL13, RNU6-1136P, RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86, ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1.
- chr8:150,584–2,165,552, 48 genes, copy number 5: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2.
- chr8:2,648,075–12,004,082, 255 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:57,674,665–57,984,761, 28 genes, copy number 8: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:63,844,700–64,162,217, 1 gene, copy number 15 (within-gene range 3–15): SRGAP1.
- chr12:63,887,379–70,920,738, 160 genes, copy number 6–20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,404. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
